TCGA case TCGA-CZ-4861 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: Harvard. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/226ce515-c12c-4195-bb5d-d6df2e135ff6

Demographics
Sex at birth: male; Race: white; Age at index: 63 years; Vital status: Dead; Days to death: 446 days (1.2 years).

Diagnoses (1)
1. Clear cell adenocarcinoma, NOS: ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 63.1 years (23,053 days); Year of diagnosis: 2005; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sorafenib; Treatment intent type: Neoadjuvant; Days to treatment start: -43 days; Days to treatment end: 32 days; Number of cycles: 1; Route of administration: Oral.

Follow-up (2 entries)
- Days to follow up: 446 days (1.2 years); Disease response: With Tumor.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Preoperative.

Molecular and laboratory tests
- Hemoglobin: Normal.
- Calcium: Normal.
- Leukocytes: Low.
- Platelets: Normal.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CZ-4861-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.8; Intermediate dimension: 0.6; Shortest dimension: 0.1.
  Slide TCGA-CZ-4861-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 5.
  Slide TCGA-CZ-4861-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10.
- Sample TCGA-CZ-4861-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CZ-4861-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.6; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: Yes; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; White cell count: Low; Lymph nodes examined: No.
- Drug treatment: Pharmaceutical therapy drug name: Sorafenib - Nexavar; Therapy regimen: OTHER, SPECIFY IN NOTES.
- Drug treatment, Route of administrations: Route of administration: PO.
- Follow-up form: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No; Performance status timing: Post Secondary Therapy.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: Subject was positive for neo-adjuvant therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 446 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 446 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 446 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-CZ-4861-01): tumor purity 0.72, ploidy 2.01, whole-genome doublings 0 (call status: legacy_call).
